Gene-level copy-number profile of tumor specimen BLGSP-71-06-00253-01B from CGCI case BLGSP-71-06-00253, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 8.1 years (2,962 days).
Specimen BLGSP-71-06-00253-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 85af6510-7914-4012-94c1-54d6423a30c2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00253-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,755 have no estimate.
https://portal.gdc.cancer.gov/files/c34e3b79-72db-4e90-8a7c-8933bc8bb6e3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 2,925; copy number 2: 53,601; copy number 3: 2,168; copy number 4: 108; copy number 5: 8; copy number 6: 3; copy number 8: 2; copy number 10: 1; copy number 35: 1.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,851,705–106,108,464, 49 genes (within-gene range 0–2): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–1): IGHVIII-16-1.
- chr21:43,465,309–43,467,298, 1 gene (within-gene range 0–10): AP001048.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr15:21,102,843–21,103,138, 1 gene, copy number 6: RN7SL400P.
- chr15:22,160,431–22,195,317, 4 genes, copy number 6–35: IGHV1OR15-1, IGHV1OR15-3, IGHV4OR15-8, IGHV1OR15-4.
- chr21:10,612,455–13,016,692, 4 genes, copy number 5: SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1.
- chr21:43,414,483–43,427,131, 1 gene, copy number 8: SIK1.
- chr21:43,461,960–43,479,534, 1 gene, copy number 10 (within-gene range 0–10): LINC00313.

Autosomal genes at a single copy (total copy number 1): 122. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
